Somatic mutation profile of tumor specimen TCGA-AA-3517-01A (aliquot TCGA-AA-3517-01A-01D-1953-10) from TCGA case TCGA-AA-3517, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.5 years (22,099 days).
Specimen TCGA-AA-3517-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe9df614-961e-4b3c-b5e4-151aeb63cbb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3517-10A (Blood Derived Normal), aliquot TCGA-AA-3517-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e33f628-c3e6-4a06-b8f5-378ed67b0e10

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ2B | c.3301C>T p.R1101* | Nonsense Mutation (SNP) | VAF 116/297 reads (39%) | catalogued as COSV54275171; called by muse, mutect2, varscan2
- FRY | c.2745G>A p.W915* | Nonsense Mutation (SNP) | VAF 60/618 reads (10%) | catalogued as COSV100969364; called by muse, mutect2
- KIAA1109 | c.7683G>C p.Q2561H | Missense Mutation (SNP) | VAF 153/312 reads (49%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); catalogued as COSV99145298, COSV99165148; called by muse, mutect2, varscan2
- MAP1A | c.5312G>A p.R1771H | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs200045630; called by muse, mutect2, varscan2
- MYLK3 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV101189127; called by muse, mutect2, varscan2
- PPP6R2 | c.2015G>A p.R672H (on ENST00000216061 / NM_001365836.1; = p.R645H on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs148234883; called by muse, mutect2, varscan2
- SIN3B | c.2791G>A p.V931I | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.707); catalogued as rs748832527, COSV56131573; called by muse, mutect2, varscan2
- SLC23A3 | c.1538G>A p.G513D (on ENST00000409878 / NM_001144889.2; = p.G396D on NM_144712.5) | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99841189; called by muse, mutect2, varscan2
- SPTA1 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 96/840 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs762361277, COSV63754736, COSV63758648; ClinVar: uncertain significance; called by muse, varscan2
- ATG2A | c.5682C>T p.P1894= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100815529; called by mutect2, varscan2
- GOLGA3 | c.3045G>A p.A1015= | Silent (SNP) | VAF 93/183 reads (51%) | catalogued as rs750957540, COSV99207896; called by muse, mutect2, varscan2
- ISLR2 | c.156C>T p.N52= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV62301795; called by muse, mutect2, varscan2
- MINDY4 | c.2136G>A p.Q712= | Silent (SNP) | VAF 117/211 reads (55%) | catalogued as COSV54675831; called by muse, mutect2, varscan2
- PI16 | c.324C>T p.H108= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV101028718; called by muse, mutect2, varscan2
- TMC4 | c.1527C>T p.L509= (on ENST00000617472 / NM_001145303.3; = p.L503= on NM_144686.4) | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV99713905; called by mutect2, varscan2
